Somatic mutation profile of tumor specimen TCGA-CC-5258-01A (aliquot TCGA-CC-5258-01A-01D-A12Z-10) from TCGA case TCGA-CC-5258, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 48.1 years (17,586 days).
Specimen TCGA-CC-5258-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 769d61e7-7fde-4c13-b608-e1a5094c195e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CC-5258-10A (Blood Derived Normal), aliquot TCGA-CC-5258-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbe5124f-cedd-4328-88e3-4431caecec0b

The open-access MAF lists 138 somatic variants for this specimen: 115 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 21, Splice Site 9, Frame Shift Del 8, Nonsense Mutation 3, In Frame Del 2, Frame Shift Ins 2, Intron 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPS2 | c.724+2T>C p.X242_splice | Splice Site (SNP) | VAF 48/94 reads (51%) | hotspot (GDC flag); catalogued as COSV59750412; called by muse, mutect2, varscan2
- ACP4 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1248948779, COSV99567665; called by muse, varscan2
- ADGRB2 | c.1700G>T p.R567L | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57074338, COSV99926649; called by muse, mutect2, varscan2
- ADGRL3 | c.3224G>T p.G1075V (on ENST00000506720 / NM_001322402.2; = p.G1007V on NM_015236.6) | Missense Mutation (SNP) | VAF 98/196 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72230835; called by muse, mutect2, varscan2
- ADGRV1 | c.4640C>T p.S1547F | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV67985618; called by muse, mutect2, varscan2
- ARTN | c.647G>T p.C216F (on ENST00000372354; = p.C224F on NM_057090.2) | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64911941; called by muse, varscan2
- ASAP1 | c.1080+1G>A p.X360_splice | Splice Site (SNP) | VAF 53/324 reads (16%) | catalogued as COSV63049706; called by muse, mutect2, varscan2
- ATP5F1B | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 152/507 reads (30%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.001); catalogued as rs11542649, COSV56261196; called by muse, mutect2, varscan2
- ATP6V0D2 | c.786C>A p.D262E | Missense Mutation (SNP) | VAF 76/90 reads (84%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53415488; called by muse, mutect2, varscan2
- CCDC88A | c.634A>G p.I212V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55063268; called by muse, mutect2, varscan2
- CHGB | c.1528C>A p.H510N | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.494); catalogued as COSV100972954, COSV66759464; called by muse, varscan2
- CNTN6 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs1481833174, COSV63161612; called by muse, mutect2, varscan2
- CNTN6 | c.1277A>T p.D426V | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.678); catalogued as COSV100609853; called by muse, mutect2, varscan2
- COL19A1 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV59593772; called by muse, mutect2, varscan2
- COL9A1 | c.731C>A p.P244H | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57885753; called by muse, mutect2, varscan2
- COP1 | c.2003A>G p.Y668C | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58169004; called by muse, mutect2, varscan2
- CSMD3 | c.3104G>T p.S1035I (on ENST00000297405 / NM_001363185.1; = p.S931I on NM_052900.3) | Missense Mutation (SNP) | VAF 47/568 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV52205137; called by muse, mutect2
- CTNNA2 | c.1554G>C p.L518F | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58138234, COSV58156326; called by muse, mutect2
- CYP39A1 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV51496452; called by muse, mutect2, varscan2
- DBN1 | c.116A>T p.D39V | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52790129; called by muse, mutect2, varscan2
- DCLRE1A | c.875A>G p.D292G | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV63748937; called by muse, mutect2, varscan2
- DDX58 | c.2741A>G p.E914G | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.258); catalogued as COSV59380719; called by muse, varscan2
- DENND5B | c.2761G>A p.A921T | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.16); catalogued as COSV60903467; called by muse, mutect2, varscan2
- DHX37 | c.2674C>T p.R892W | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369049552; called by muse, mutect2, varscan2
- DYM | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV53986406; called by muse, mutect2, varscan2
- EGFLAM | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.075); catalogued as rs369204325, COSV59305298; called by muse, mutect2, varscan2
- EIF2AK3 | c.2803C>T p.H935Y | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57548533; called by muse, mutect2, varscan2
- FAM155A | c.145A>C p.T49P | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65566089; called by muse, mutect2, varscan2
- FBN2 | c.7626C>A p.N2542K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52519429, COSV99328323; called by muse, mutect2, varscan2
- FGD6 | c.1538C>G p.A513G | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV59693882; called by muse, mutect2, varscan2
- FGFRL1 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV53257831; called by muse, mutect2, varscan2
- FOXG1 | c.1080C>A p.N360K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV57397283, COSV57397953; called by muse, varscan2
- GABRR2 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 79/217 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV68765168; called by muse, mutect2, varscan2
- GCN1 | c.5606C>T p.S1869F | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56104062; called by muse, mutect2, varscan2
- GFRAL | c.959C>A p.P320Q | Missense Mutation (SNP) | VAF 129/418 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.168); catalogued as COSV100475065, COSV61234494; called by mutect2, varscan2
- GMIP | c.2863G>A p.A955T | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs747924692, COSV52557013; called by muse, mutect2, varscan2
- GPR135 | c.1165A>G p.I389V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV67749662; called by muse, mutect2
- GPRIN2 | c.577C>G p.Q193E | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV65401244; called by muse, mutect2, varscan2
- HEATR6 | c.219+1G>A p.X73_splice | Splice Site (SNP) | VAF 12/35 reads (34%) | catalogued as rs1447439758, COSV51746295; called by muse, varscan2
- HHIPL2 | c.1711G>C p.E571Q | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100597145, COSV58565679; called by muse, mutect2, varscan2
- IGSF3 | c.2935C>T p.R979C (on ENST00000369486 / NM_001007237.3; = p.R999C on NM_001542.4) | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1279277775, CD1411593, COSV59586547; called by muse, varscan2
- IGSF9B | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.505); catalogued as COSV58068851; called by muse, mutect2, varscan2
- JARID2 | c.2708T>A p.L903Q | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59190884; called by muse, mutect2, varscan2
- KCND2 | c.259C>A p.R87S | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100478099, COSV58583837; called by muse, mutect2, varscan2
- KIF14 | c.4694A>G p.H1565R | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV66262143; called by muse, mutect2
- KIF26B | c.1831C>G p.L611V | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63643573; called by muse, mutect2, varscan2
- KYNU | c.583-1G>A p.X195_splice | Splice Site (SNP) | VAF 11/45 reads (24%) | catalogued as COSV51585083; called by muse, mutect2, varscan2
- LEO1 | c.704C>G p.P235R | Missense Mutation (SNP) | VAF 84/506 reads (17%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV55176077; called by muse, mutect2, varscan2
- LRP1 | c.4291G>T p.G1431C | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54514268, COSV54525175; called by muse, mutect2, varscan2
- LTBP2 | c.2105G>T p.G702V | Missense Mutation (SNP) | VAF 69/162 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1401080194, COSV56209431, COSV56214969; called by muse, mutect2, varscan2
- NLGN1 | c.1165del p.Q389Kfs*5 | Frame Shift Del (DEL) | VAF 30/121 reads (25%) | catalogued as COSV64350409; called by mutect2, pindel, varscan2
- OLFM1 | c.1204G>A p.A402T (on ENST00000371793 / NM_001282611.2; = p.A384T on NM_014279.5) | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53279064; called by muse, mutect2, varscan2
- OLFML2A | c.895C>A p.Q299K | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV56583875; called by muse, mutect2, varscan2
- OR10A3 | c.809C>G p.T270S | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.036); catalogued as rs758667752, COSV62459635; called by muse, mutect2, varscan2
- OR10J5 | c.77C>A p.T26N | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV58386388; called by muse, mutect2, varscan2
- OR11A1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1188530059, COSV65820775; called by muse, mutect2, varscan2
- OR4K14 | c.258C>A p.F86L | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV100520488, COSV59292890, COSV59293074; called by muse, mutect2, varscan2
- OR6C65 | c.305dup p.L102Ffs*18 | Frame Shift Ins (INS) | VAF 40/122 reads (33%) | catalogued as rs753853776; called by mutect2, varscan2
- OR8K5 | c.534C>A p.Y178* | Nonsense Mutation (SNP) | VAF 25/100 reads (25%) | catalogued as COSV57889420; called by muse, mutect2, varscan2
- OTUD7B | c.2168G>T p.G723V | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs376252200; called by muse, mutect2, varscan2
- PAGE2 | c.319+1G>A p.X107_splice | Splice Site (SNP) | VAF 93/281 reads (33%) | catalogued as COSV66596011; called by muse, mutect2, varscan2
- PARP2 | c.602A>G p.Y201C | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51638474; called by muse, mutect2, varscan2
- PCBD2 | c.85-1G>C p.X29_splice | Splice Site (SNP) | VAF 22/119 reads (18%) | catalogued as COSV54737611; called by muse, mutect2, varscan2
- PCNT | c.7799C>T p.A2600V | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762085456, COSV64029309; called by muse, mutect2, varscan2
- PDCD6IP | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.459); catalogued as rs1242344780, COSV56243661; called by muse, varscan2
- PER2 | c.1628-1G>A p.X543_splice | Splice Site (SNP) | VAF 46/119 reads (39%) | catalogued as rs1161258742, COSV54524436; called by muse, mutect2, varscan2
- PIGQ | c.1023C>G p.D341E | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV50314808; called by muse, mutect2, varscan2
- PKHD1 | c.7616T>C p.I2539T | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV61880141; called by muse, mutect2, varscan2
- PKHD1L1 | c.5389A>C p.N1797H | Missense Mutation (SNP) | VAF 26/442 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV65745043; called by muse, mutect2
- PKHD1L1 | c.5980G>C p.V1994L | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as COSV65745048; called by muse, mutect2
- PLEKHB1 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99909391; called by muse, varscan2
- PLK4 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 107/307 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs1044647621, COSV54637829; called by muse, mutect2, varscan2
- POSTN | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.171); catalogued as rs1161203594, COSV65713291; called by muse, mutect2, varscan2
- POU6F2 | c.1801G>T p.G601W | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775692137, COSV68874768, COSV68884614; called by muse, mutect2, varscan2
- PRKCH | c.1654G>T p.A552S | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.938); catalogued as COSV60646823, COSV60649045; called by muse, mutect2, varscan2
- PRR27 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 88/312 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100748751; called by muse, mutect2, varscan2
- REV3L | c.7160A>T p.H2387L | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV62619805; called by muse, mutect2, varscan2
- RHOBTB3 | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs772887011, COSV66102302; called by muse, mutect2, varscan2
- RXRA | c.938T>C p.F313S | Missense Mutation (SNP) | VAF 134/240 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs749277866, COSV100709242; called by muse, varscan2
- SAMD15 | c.1229C>T p.T410I | Missense Mutation (SNP) | VAF 77/382 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as rs755976933, COSV53626640; called by muse, mutect2, varscan2
- SCN2A | c.3263A>G p.D1088G | Missense Mutation (SNP) | VAF 87/279 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as COSV51844386; called by muse, mutect2, varscan2
- SHANK2 | c.1879G>T p.V627L | Missense Mutation (SNP) | VAF 80/269 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV53602192; called by muse, mutect2, varscan2
- SLC5A7 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50892989; called by muse, mutect2, varscan2
- SLC8A3 | c.172G>T p.V58F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV100776133; called by muse, mutect2, varscan2
- SNX10 | c.576T>A p.C192* | Nonsense Mutation (SNP) | VAF 107/349 reads (31%) | catalogued as COSV58401205; called by muse, mutect2, varscan2
- SRSF7 | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 177/486 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1018971891, COSV57447315; called by muse, mutect2, varscan2
- SYVN1 | c.132A>G p.A44= | Splice Region (SNP) | VAF 27/79 reads (34%) | catalogued as COSV53695755; called by muse, mutect2
- TGM7 | c.1618G>A p.G540S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.573); catalogued as rs774865695, COSV71772884; called by muse, mutect2, varscan2
- TLR9 | c.2833G>A p.G945S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62347105; called by muse, mutect2, varscan2
- TP53 | c.788del p.N263Ifs*82 | Frame Shift Del (DEL) | VAF 26/66 reads (39%) | catalogued as COSV53208998; called by mutect2, pindel, varscan2
- TRIOBP | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as rs764470749, COSV60378995; called by muse, mutect2, varscan2
- TRMT61B | c.1085+1G>A p.X362_splice | Splice Site (SNP) | VAF 53/179 reads (30%) | catalogued as rs1443438783, COSV100066247; called by muse, mutect2, varscan2
- TTC30A | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV53697385, COSV99610615, COSV99610790; called by muse, mutect2, varscan2
- TTLL13P | c.550T>A p.Y184N | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV60038293; called by muse, mutect2, varscan2
- TTPA | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 68/332 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV52646966; called by muse, mutect2, varscan2
- UGT2A1 | c.1341C>A p.H447Q | Missense Mutation (SNP) | VAF 133/278 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV54142449; called by muse, mutect2, varscan2
- UTRN | c.1066A>G p.M356V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62337651; called by muse, mutect2, varscan2
- VAMP1 | c.205G>C p.A69P | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV56947204; called by muse, mutect2, varscan2
- ZFYVE9 | c.2114G>T p.C705F | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55094890; called by muse, mutect2, varscan2
- ZNF677 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs1465473511, COSV100447806, COSV61720489; called by muse, mutect2, varscan2
- ZNF681 | c.1276A>G p.K426E | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV68074474; called by muse, varscan2
- ACACA | c.4828A>G p.I1610V | Missense Mutation (SNP) | VAF 103/204 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ALOX15B | c.1249del p.R417Gfs*25 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel
- ARID1A | c.2181_2185del p.P728Qfs*87 | Frame Shift Del (DEL) | VAF 79/170 reads (46%) | called by mutect2, pindel, varscan2
- CHST15 | c.1673G>A p.W558* | Nonsense Mutation (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- DDX58 | c.2720_2726del p.K907Rfs*29 | Frame Shift Del (DEL) | VAF 44/109 reads (40%) | called by pindel, varscan2
- FRG2C | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 61/483 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- GALM | c.805_813del p.L269_V271del | In Frame Del (DEL) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- GPR89A | c.176_199del p.I59_L66del | In Frame Del (DEL) | VAF 70/413 reads (17%) | called by mutect2, varscan2
- ICE2 | c.2294_2295+28del p.X765_splice | Splice Site (DEL) | VAF 18/114 reads (16%) | called by mutect2, pindel
- KIF20B | c.1081_1082del p.Q361Dfs*2 | Frame Shift Del (DEL) | VAF 43/291 reads (15%) | called by mutect2, pindel, varscan2
- LYZL6 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MTIF2 | c.1469del p.S490* | Frame Shift Del (DEL) | VAF 69/572 reads (12%) | called by mutect2, pindel, varscan2
- SLC12A3 | c.1992del p.F665Sfs*7 | Frame Shift Del (DEL) | VAF 33/73 reads (45%) | called by mutect2, pindel, varscan2
- ZNF99 | c.430dup p.I144Nfs*5 | Frame Shift Ins (INS) | VAF 44/153 reads (29%) | called by mutect2, pindel, varscan2
- ASB15 | c.1446T>C p.C482= | Silent (SNP) | VAF 50/129 reads (39%) | catalogued as COSV51926696; called by muse, mutect2, varscan2
- ASB2 | c.1158C>T p.G386= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs1185256349, COSV60111435, COSV60112408; called by muse, mutect2, varscan2
- C1QTNF4 | c.681C>T p.G227= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs1318559447, COSV56783635; called by muse, varscan2
- CADM1 | c.879G>C p.L293= | Silent (SNP) | VAF 24/157 reads (15%) | catalogued as COSV59012704; called by muse, mutect2, varscan2
- CNOT3 | c.63C>T p.G21= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs149889819, COSV55364165; called by muse, mutect2, varscan2
- DNAH9 | c.9480G>A p.A3160= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs774215663, COSV52354167; called by muse, mutect2, varscan2
- FNDC3A | c.534A>G p.R178= (on ENST00000492622 / NM_001079673.2; = p.R122= on NM_014923.5) | Silent (SNP) | VAF 53/122 reads (43%) | catalogued as rs1215919950, COSV65695696; called by muse, mutect2, varscan2
- GIMAP2 | c.690G>T p.V230= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV56235522; called by muse, mutect2, varscan2
- GPRIN2 | c.1128G>T p.P376= | Silent (SNP) | VAF 20/224 reads (9%) | catalogued as rs111800394, COSV65401248, COSV65401530; called by muse, mutect2
- HYDIN | c.12489G>C p.V4163= | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as COSV66639520; called by muse, mutect2, varscan2
- KIAA0100 | c.810C>T p.F270= | Silent (SNP) | VAF 116/335 reads (35%) | catalogued as COSV66493727; called by muse, mutect2, varscan2
- LNX2 | c.465T>G p.T155= | Silent (SNP) | VAF 63/126 reads (50%) | catalogued as COSV60336219; called by muse, mutect2, varscan2
- LRP6 | c.3600A>G p.Q1200= | Silent (SNP) | VAF 61/179 reads (34%) | catalogued as COSV53788727; called by muse, mutect2, varscan2
- NAP1L3 | c.828A>T p.A276= | Silent (SNP) | VAF 157/217 reads (72%) | catalogued as COSV59075980; called by muse, mutect2, varscan2
- NAT10 | c.501G>A p.V167= | Silent (SNP) | VAF 57/201 reads (28%) | catalogued as COSV57664329; called by muse, mutect2, varscan2
- NPHP3 | c.2982A>G p.V994= | Silent (SNP) | VAF 59/338 reads (17%) | catalogued as COSV58630901; called by muse, mutect2, varscan2
- PTPRM | c.1809C>T p.T603= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs781228109, COSV59863811; called by muse, mutect2, varscan2
- RIMBP2 | c.712C>A p.R238= | Silent (SNP) | VAF 131/374 reads (35%) | catalogued as COSV55469326, COSV55475139, COSV55479677; called by muse, mutect2, varscan2
- SPRY2 | c.390C>G p.S130= | Silent (SNP) | VAF 25/164 reads (15%) | catalogued as COSV65701483; called by muse, mutect2, varscan2
- TGFB1 | c.615G>T p.R205= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as COSV55725291; called by muse, mutect2, varscan2
- TRPA1 | c.2463C>A p.P821= | Silent (SNP) | VAF 45/292 reads (15%) | catalogued as COSV51563927; called by muse, mutect2, varscan2
- PDE4D | c.455+306820A>G | Intron (SNP) | VAF 69/154 reads (45%) | catalogued as COSV58960018; called by muse, mutect2, varscan2
- SUGT1P4-STRA6LP | n.1381C>G | RNA (SNP) | VAF 56/101 reads (55%) | called by muse, mutect2, varscan2
